Somatic mutation profile of tumor specimen TCGA-A7-A26H-01A (aliquot TCGA-A7-A26H-01A-11D-A167-09) from TCGA case TCGA-A7-A26H, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.3 years (26,423 days).
Specimen TCGA-A7-A26H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edf85b74-0235-409f-b5a9-522b914da71d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A26H-10A (Blood Derived Normal), aliquot TCGA-A7-A26H-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/468c751e-86b3-47d9-95b5-2de6133d00b9

The open-access MAF lists 124 somatic variants for this specimen: 91 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 32, Nonsense Mutation 12, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1, In Frame Ins 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.10942G>T p.E3648* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs397514576, CM074682, COSV52502990, COSV52506625; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 19/51 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.6010C>T p.R2004C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs142315228; called by muse, mutect2, varscan2
- ABCF2 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV55180978; called by muse, mutect2, varscan2
- ADCY9 | c.3996C>A p.D1332E | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV53571599; called by muse, mutect2, varscan2
- ALG13 | c.2090G>T p.R697L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV52635322; called by muse, mutect2, varscan2
- ANKLE2 | c.2257G>C p.D753H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as rs376936921; called by muse, mutect2, varscan2
- ANKRD2 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs961343580, COSV100081078; called by muse, mutect2
- ANOS1 | c.856+1G>T p.X286_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV52916074; called by muse, mutect2, varscan2
- AQP5 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52231082; called by muse, mutect2
- ASTN1 | c.2097C>A p.C699* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV56061724; called by muse, mutect2, varscan2
- ATXN2 | c.2810C>T p.S937L (on ENST00000550104; = p.S777L on NM_002973.4) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as rs761520179, COSV66481348; called by muse, mutect2, varscan2
- B4GALT5 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV65492693; called by muse, mutect2, varscan2
- BDP1 | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV62428987; called by muse, mutect2, varscan2
- BOD1L1 | c.2668G>C p.E890Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50006641; called by muse, mutect2, varscan2
- BRD4 | c.1638G>C p.K546N | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as rs761158744, COSV54582426; called by muse, mutect2, varscan2
- C7orf50 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV62472818; called by muse, mutect2, varscan2
- CACNA1A | c.3880G>C p.E1294Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64189912; called by muse, mutect2, varscan2
- CACNA1H | c.2322G>A p.W774* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as rs1451924937, COSV61984016; called by muse, mutect2, varscan2
- CDC42BPA | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62002718; called by muse, mutect2, varscan2
- CHD4 | c.1443G>A p.T481= (on ENST00000357008 / NM_001363606.2; = p.T494= on NM_001273.5) | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as rs1307844514, COSV100537760; called by muse, mutect2
- CHD7 | c.6571G>C p.E2191Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as CD118991, COSV71107280; called by muse, mutect2, varscan2
- COL6A1 | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100720213, COSV62611562; called by muse, mutect2, varscan2
- COL9A1 | c.2087T>A p.I696K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.415); catalogued as COSV57878783; called by muse, mutect2, varscan2
- CRMP1 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs768870212, COSV61478281; called by muse, mutect2, varscan2
- CTNNB1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV62690146; called by muse, mutect2, varscan2
- CTSF | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59747575; called by muse, mutect2, varscan2
- DENND1A | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV65322492; called by muse, mutect2, varscan2
- DIAPH3 | c.1876C>T p.P626S (on ENST00000400324 / NM_001042517.2; = p.P363S on NM_030932.3) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV57365115; called by muse, mutect2, varscan2
- DNAJC16 | c.1565C>G p.S522* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV65448082; called by muse, mutect2, varscan2
- DYNC1H1 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs988847052, COSV64136427; called by muse, mutect2, varscan2
- ECT2 | c.2501C>A p.S834* (on ENST00000392692 / NM_001349098.2; = p.S803* on NM_018098.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV51688733, COSV99222002; called by muse, mutect2, varscan2
- EMC2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55207903; called by muse, mutect2, varscan2
- FMNL2 | c.2992C>T p.L998F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.749); catalogued as rs1452746443, COSV56490311; called by muse, mutect2, varscan2
- GABBR2 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as rs1041791146, COSV52293501, COSV99411057; called by muse, mutect2, varscan2
- GON4L | c.4558G>C p.E1520Q | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99675991; called by muse, mutect2
- H3C2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV52518070, COSV52519869; called by muse, mutect2
- HIPK2 | c.1945G>C p.D649H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61225686; called by muse, mutect2, varscan2
- HNF1A | c.378C>A p.H126Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV57459400; called by muse, mutect2, varscan2
- IL20RA | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV57356395; called by muse, mutect2, varscan2
- JUN | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as rs370449022, COSV64664968; called by mutect2, varscan2
- KCNQ1 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.539); catalogued as rs749351255, COSV50100550; called by muse, mutect2, varscan2
- KIAA0895 | c.359A>C p.Y120S (on ENST00000297063 / NM_001100425.2; = p.Y69S on NM_015314.3) | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99767294; called by muse, mutect2
- LGALS1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV53221806; called by muse, mutect2, varscan2
- LRP2 | c.9265G>A p.E3089K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs745739674, COSV55541324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP2 | c.1633G>C p.D545H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as COSV99561979; called by muse, mutect2
- MAP2K4 | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62254999; called by muse, mutect2, varscan2
- MAP2K6 | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV63005102, COSV63005309; called by muse, mutect2, varscan2
- MDM1 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs747994706, COSV57444517; called by muse, mutect2, varscan2
- MKI67 | c.1398A>C p.K466N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs757873177, COSV64072607; called by muse, mutect2, varscan2
- MNAT1 | c.827G>C p.R276T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54186921; called by muse, mutect2, varscan2
- MUC2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0); catalogued as rs1488103482; called by muse, mutect2, varscan2
- NADK | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1490265077, COSV58269205; called by muse, mutect2, varscan2
- NCOA3 | c.3178C>T p.L1060F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.25); catalogued as COSV59065743; called by muse, mutect2, varscan2
- OR4C15 | c.103T>G p.C35G | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV100116173; called by muse, mutect2, varscan2
- OR5K3 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV67349681; called by muse, mutect2, varscan2
- PCBP2 | c.482_483insT p.Q161Hfs*61 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | catalogued as COSV63727970; called by mutect2, pindel, varscan2
- PCDHA10 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.292); catalogued as rs782552455, COSV56478025, COSV56547628; called by muse, mutect2
- PCDHA9 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs1313299293, COSV100969035, COSV65323556; called by muse, mutect2, varscan2
- PCDHB4 | c.2284G>T p.E762* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV52019614, COSV52024347; called by muse, mutect2, varscan2
- PCIF1 | c.1865C>G p.S622C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as COSV59816055; called by muse, mutect2, varscan2
- PKHD1 | c.7618C>T p.L2540F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1335068981, COSV100583815, COSV100584816; called by muse, mutect2, varscan2
- PPP1R13B | c.10A>T p.M4L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV52448787; called by muse, mutect2, varscan2
- PRMT9 | c.2408C>T p.S803L | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99669822; called by muse, mutect2
- PRPF40A | c.914T>G p.M305R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.34); catalogued as rs1351460482, COSV62956673; called by muse, mutect2, varscan2
- RBBP6 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV60503206; called by muse, mutect2, varscan2
- RBBP6 | c.2220G>C p.K740N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV100155085; called by muse, mutect2
- RGS3 | c.643C>T p.Q215* (on ENST00000350696 / NM_001282923.2; = p.Q103* on NM_017790.4) | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as rs547113494, COSV58277054; called by muse, mutect2, varscan2
- RNGTT | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV55646238; called by muse, mutect2
- SERINC5 | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.421); catalogued as COSV101549146, COSV101549148; called by muse, mutect2
- SLC6A5 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as COSV54223697; called by muse, mutect2, varscan2
- SLC9C2 | c.363G>T p.L121F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV100877039; called by muse, mutect2
- SLITRK1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV65674300; called by muse, mutect2, varscan2
- SMARCA1 | c.2665G>T p.G889C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64410894; called by muse, mutect2, varscan2
- ST3GAL3 | c.332C>T p.T111M (on ENST00000361392 / NM_174964.4; = p.T96M on NM_006279.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs376537870; called by muse, mutect2, varscan2
- TAOK1 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV55588311; called by muse, mutect2, varscan2
- TMEM117 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs769011235, COSV56894755; called by muse, mutect2, varscan2
- TMEM94 | c.2156G>T p.G719V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58593097, COSV58594279; called by muse, mutect2, varscan2
- TNRC6B | c.4130C>T p.S1377F (on ENST00000454349 / NM_001162501.2; = p.S1267F on NM_015088.3) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.988); catalogued as COSV57289267; called by muse, mutect2, varscan2
- TSPYL2 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs782709479, COSV60233578; called by muse, mutect2, varscan2
- WDR7 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV54348362; called by muse, mutect2, varscan2
- XPR1 | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV62554581; called by muse, mutect2, varscan2
- ZNF461 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV64452872, COSV64455626; called by muse, mutect2, varscan2
- ZNF461 | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV64452894; called by muse, mutect2, varscan2
- ZNF461 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.113); catalogued as COSV100831377, COSV64452904; called by muse, mutect2, varscan2
- ZNF701 | c.1499G>C p.G500A (on ENST00000301093; = p.G434A on NM_018260.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as rs774108356, COSV56523158, COSV99990821; called by muse, mutect2, varscan2
- ZNF792 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV68692724; called by muse, mutect2, varscan2
- ZNHIT6 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); catalogued as COSV65326614; called by muse, mutect2, varscan2
- BRCA1 | c.2061_2064del p.T688Vfs*12 | Frame Shift Del (DEL) | VAF 32/121 reads (26%) | called by mutect2, pindel, varscan2
- KDELR1 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- TOB1 | c.271_276dup p.S91_V92dup | In Frame Ins (INS) | VAF 21/117 reads (18%) | called by mutect2, varscan2
- ABHD16B | c.594C>T p.S198= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs886272898, COSV53862260; called by muse, mutect2
- ATP6AP1 | c.621G>A p.L207= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV63895248; called by muse, mutect2, varscan2
- CATSPERB | c.750G>C p.T250= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56423929, COSV99831907; called by muse, mutect2
- CFAP65 | c.879G>A p.G293= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV55389390; called by muse, mutect2, varscan2
- FANCM | c.4503G>A p.Q1501= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99951768; called by muse, mutect2
- FNIP2 | c.2814G>A p.Q938= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV52436677; called by muse, mutect2, varscan2
- G0S2 | c.153G>A p.T51= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs759472154, COSV100884486; called by muse, mutect2
- GFPT2 | c.456G>C p.L152= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV53806444; called by muse, mutect2, varscan2
- GPR12 | c.582C>T p.L194= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1465621706, COSV101198030; called by muse, mutect2
- GPX4 | c.510C>T p.I170= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs745797291, COSV62318675; called by muse, mutect2, varscan2
- GRM3 | c.777G>A p.V259= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV64467378; called by muse, mutect2, varscan2
- IDH1 | c.264G>A p.L88= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs758622511, COSV61616735, COSV61631852; called by muse, mutect2, varscan2
- IGF2R | c.1422C>T p.L474= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1412058859, COSV63626459; called by muse, mutect2, varscan2
- ITGBL1 | c.921G>A p.G307= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs764428254, COSV66005346; called by muse, mutect2, varscan2
- KRBA2 | c.1404C>T p.D468= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs572316984, COSV58778654; called by muse, mutect2, varscan2
- L1CAM | c.3351C>T p.F1117= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs781828655, COSV62826859; called by muse, mutect2, varscan2
- LILRB2 | c.1488G>A p.Q496= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV58743588, COSV58744966; called by muse, mutect2, varscan2
- LRGUK | c.1188G>A p.V396= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV53634196; called by muse, mutect2, varscan2
- MAP2 | c.1941T>C p.D647= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52281452; called by mutect2, varscan2
- NF1 | c.2556C>T p.L852= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs771308677, COSV62193474; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP7 | c.954C>T p.Y318= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV60171157; called by muse, mutect2, varscan2
- OR51D1 | c.627G>A p.V209= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV62913881; called by muse, mutect2, varscan2
- OR5D14 | c.24G>A p.L8= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV59455413; called by muse, mutect2, varscan2
- OTULIN | c.921C>G p.L307= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1197564771, COSV52504919, COSV52507280; called by muse, mutect2, varscan2
- PCIF1 | c.1536C>T p.F512= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs753235115, COSV59816052; called by muse, mutect2, varscan2
- PCTP | c.282C>T p.N94= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs745946648, COSV99273911; called by muse, mutect2
- PDS5B | c.2427T>G p.T809= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV59723519; called by muse, mutect2, varscan2
- PGK1 | c.267G>A p.L89= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV64831678; called by muse, mutect2, varscan2
- POLR3E | c.1752C>T p.L584= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV55398923; called by muse, mutect2, varscan2
- SCML1 | c.525C>T p.L175= (on ENST00000380041 / NM_001037540.3; = p.L148= on NM_006746.6) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV66240376; called by muse, mutect2, varscan2
- SLC22A16 | c.600G>A p.A200= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs377346650; called by muse, mutect2, varscan2
- ZNF461 | c.1368C>G p.L456= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV64452884, COSV64455033; called by muse, mutect2, varscan2
- OSCAR | c.*427G>C | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as COSV52927013; called by muse, mutect2, varscan2
